Somatic mutation profile of tumor specimen TARGET-10-PATDFE-09A (aliquot TARGET-10-PATDFE-09A-01D) from TARGET case TARGET-10-PATDFE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,835 days).
Specimen TARGET-10-PATDFE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96dc8ace-4ce3-4553-92a9-cc636e472f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDFE-10A (Blood Derived Normal), aliquot TARGET-10-PATDFE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89c6d107-aa5b-465d-b558-7a59e8fd7429

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 3, 3'UTR 3, Silent 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP2B3 | c.2573C>T p.T858M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54844911; called by muse, mutect2, varscan2
- CMAS | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57556423; called by muse, mutect2, varscan2
- CNOT3 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV55362378; called by muse, mutect2, varscan2
- CTCF | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50466124; called by muse, mutect2, varscan2
- HUWE1 | c.7198C>T p.R2400* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV53342618; called by muse, mutect2, varscan2
- MARCHF7 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs901023756; called by muse, mutect2
- PTCH1 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs771238114, COSV59471075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPTIN10 | c.501_502del p.Y167* | Nonsense Mutation (DEL) | VAF 16/34 reads (47%) | catalogued as COSV61780004; called by mutect2, pindel*, varscan2*
- SYBU | c.249C>A p.S83R (on ENST00000276646 / NM_001099754.2; = p.S82R on NM_017786.6) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52617043; called by muse, mutect2, varscan2
- NOTCH1 | c.4848_4858del p.F1617Rfs*22 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel*, varscan2
- COMMD3-BMI1 | c.12G>A p.S4= | Silent (SNP) | VAF 21/27 reads (78%) | called by muse, mutect2, varscan2
- LAMA2 | c.243G>A p.P81= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs766642494, COSV70344877; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1344C>A p.G448= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs762235232; called by muse, mutect2, varscan2
- BAGE2 | n.168G>T | RNA (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- ID4 | c.*4G>A | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- RABL3 | c.*221G>T | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- YY2 | c.*48G>A | 3'UTR (SNP) | VAF 18/39 reads (46%) | catalogued as rs771303094; called by muse, mutect2, varscan2
